FM case AD13429 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms.
https://portal.gdc.cancer.gov/cases/a86136a0-09f1-4523-8c5c-bfe6e2d0416b

Male, 65.3 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3); specimen biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
